Somatic mutation profile of tumor specimen TCGA-BR-8384-01A (aliquot TCGA-BR-8384-01A-21D-2394-08) from TCGA case TCGA-BR-8384, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 69.2 years (25,281 days).
Specimen TCGA-BR-8384-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 108978d0-7706-4782-923d-f50691c09576.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8384-10A (Blood Derived Normal), aliquot TCGA-BR-8384-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fea89007-8751-4db1-9ad3-ef49843fa8b3

The open-access MAF lists 45 somatic variants for this specimen: 36 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 8, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC12 | c.1844G>A p.R615H | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs547878738, COSV60911544, COSV60913298; called by muse, mutect2
- ASTN1 | c.3526G>A p.A1176T | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62491803, COSV62494609; called by muse, mutect2
- BRCA2 | c.3361T>A p.S1121T | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as COSV66448801; called by muse, mutect2
- BRCA2 | c.3475T>A p.C1159S | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV66448808; called by muse, mutect2
- CDH8 | c.2171T>G p.F724C | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54850739; called by muse, mutect2
- CHFR | c.886G>C p.D296H (on ENST00000432561 / NM_001161345.1; = p.D255H on NM_018223.2) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57172291, COSV99905161; called by mutect2, varscan2
- CHRM2 | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs201605223, COSV57765987; called by muse, mutect2
- CLUL1 | c.1241C>T p.S414F | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV58111359; called by muse, mutect2, varscan2
- CSMD3 | c.1427A>T p.E476V (on ENST00000297405 / NM_001363185.1; = p.E372V on NM_052900.3) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52111472; called by muse, mutect2, varscan2
- DHX36 | c.1811G>A p.G604E | Missense Mutation (SNP) | VAF 18/251 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57671080; called by muse, mutect2
- DPRX | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.369); catalogued as rs752355371, COSV64949213; called by muse, mutect2
- EMC4 | c.109G>T p.G37C | Missense Mutation (SNP) | VAF 11/221 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV50784531; called by muse, mutect2
- GGTLC1 | c.176+1G>A p.X59_splice | Splice Site (SNP) | VAF 5/42 reads (12%) | catalogued as rs775862580, COSV53846391; called by muse, mutect2, varscan2
- KCNIP3 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764036281, COSV54666102; called by muse, mutect2
- KRTAP21-2 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.17); catalogued as rs1457142962, COSV61683914; called by muse, mutect2
- LATS1 | c.2360G>C p.G787A | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53586526, COSV53597892, COSV53603872; called by muse, mutect2, varscan2
- MAGEC1 | c.2113C>A p.L705M | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV53568657; called by muse, mutect2, varscan2
- MUC16 | c.113C>A p.T38N | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV101201594; called by muse, mutect2
- MYH4 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs755708452, COSV55113074; called by muse, mutect2
- OBSL1 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1308055969, COSV54713467; called by muse, mutect2
- OCA2 | c.1420T>G p.F474V | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62339542; called by muse, mutect2
- OR2M5 | c.418A>G p.I140V | Missense Mutation (SNP) | VAF 34/441 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV63545771, COSV63547046; called by muse, mutect2
- OR5AS1 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 21/353 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.589); catalogued as rs775263125, COSV57980915; called by muse, mutect2
- OR5K1 | c.557G>A p.R186K | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0.246); catalogued as rs747663094, COSV60303589; called by muse, mutect2
- PCDH11X | c.2892A>C p.Q964H | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53439195; called by muse, mutect2, varscan2
- PSD3 | c.1561G>A p.V521I | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs558057781, COSV58962444; called by muse, mutect2
- PSG2 | c.920C>G p.A307G | Missense Mutation (SNP) | VAF 32/393 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.593); catalogued as COSV61544611; called by muse, mutect2
- PXDN | c.886T>G p.L296V | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.158); catalogued as COSV53225843; called by muse, mutect2
- RGS7 | c.963A>C p.E321D | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV58531821; called by muse, mutect2
- RPL35 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs941598782; called by muse, mutect2
- SIPA1L2 | c.4727G>T p.W1576L | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV53384283; called by muse, mutect2
- TTN | c.5799A>C p.E1933D (on ENST00000591111; = p.E1887D on NM_003319.4) | Missense Mutation (SNP) | VAF 11/244 reads (5%) | PolyPhen probably damaging (0.99); catalogued as COSV59905732; called by muse, mutect2
- UNC5D | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54772511; called by muse, mutect2
- ZNF274 | c.38C>G p.P13R | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58763139; called by muse, mutect2
- ZNF99 | c.1769A>G p.E590G | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs752556885, COSV68054895; called by muse, mutect2, varscan2
- DPPA4 | c.737T>G p.V246G | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2
- CHD5 | c.1074C>T p.C358= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs147670357; called by muse, mutect2, varscan2
- CYFIP1 | c.1719A>G p.K573= | Silent (SNP) | VAF 5/112 reads (4%) | called by muse, mutect2
- DCAF12L2 | c.138G>A p.A46= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV63580461; called by muse, mutect2
- FASTK | c.810G>A p.T270= | Silent (SNP) | VAF 5/95 reads (5%) | catalogued as rs1357650430, COSV99879982; called by muse, mutect2
- HIF1AN | c.783C>T p.Y261= | Silent (SNP) | VAF 15/172 reads (9%) | catalogued as rs200626557, COSV54499532; called by muse, mutect2
- MUC16 | c.114C>A p.T38= | Silent (SNP) | VAF 4/70 reads (6%) | catalogued as COSV101201593; called by muse, mutect2
- NSD2 | c.3681G>A p.R1227= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as rs888776481, COSV56386964; called by muse, mutect2
- SEC16A | c.3111T>G p.L1037= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV51522018; called by muse, mutect2, varscan2
- SREBF1 | c.92-3073G>C | Intron (SNP) | VAF 11/84 reads (13%) | catalogued as COSV99889460; called by muse, mutect2
